Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A7SF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A7SF-01A (Primary Tumor).

[page 1 of 3]
Frozen Section(1-2)

< Frozen permanent diagnosis >

A. "IVC mass" , biopsy:

Cavernous hemangioma

B. Liver, segmentectomy :
HEPATOCELLULAR CARCINOMA

Tumor number: one
Satellite nodule: no
Location : S8
Gross type: expanding nodular
Size(cm): 4.3x4.2cm
Differentiation: The worst differentiation: Edmondson grade III
Differentiation: The major differentiation: Edmondson grade II
Histologic type : microtrabecular
Cell type : hepatic
Tumor necrosis : no
Hemorrhage : yes (10 %)
Fatty change : no
Fibrous capsule : partial
Infiltration of capsule : no
Septum formation : yes
Surgical margin invasion : no(margin of the clearance 0.5 cm)
Serosa invasion: no
Portal vein invasion : no
Bile duct invasion : no
Hepatic vein invasion : no
Hepatic artery invasion : no
Microvessel invasion : no
Intrahepatic metastasis : no
Multicentric occurrence : no
T stage : pT1

Non-tumor liver

Chronic hepatitis : yes

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
JW 10/4/13

[page 2 of 3]
Frozen Section(1-2)

Etiology : HCV

Grade, lobular : none

Grade, portoperiportal : minimal

Stage(fibrosis) : septal fibrosis with early cirrhosis

Dysplastic nodule : no

Ductal epithelial dysplasia : no

Other liver disease : no

C. Gallbladder, cholecystectomy:

. Cholesterol polyp

< Immunohistochemical and special stain results, block B9>

Iron: Negative

Cytokeratin 7: Positive in bile duct

A. The specimen submitted for frozen section consists of a piece of reddish yellow soft tissue, measuring 0.9x0.4x0.2cm, clinically labeled as "mass in front IVC". Entirely embedded.

<Frozen diagnosis>

A. Soft tissue, in front IVC, biopsy :

Suspicious for lymphangioma (ISP)

The diagnosis was informed to Dr. at

B. The specimen received in formalin consists of a product of liver segmentectomy, measuring 8x7x5cm and weighing 85gm. The serosa surface shows a subcapsular mass. On section, there is a expanding nodular type mass, measuring 4.2x4x3cm. The cut surface of the mass is yellowish and myxoid with multiple hemorrhagic foci. The mass is 0.5cm apart from parenchyme resection. Remaining parenchyme is unremarkable. Representative sections are embedded in nine cassettes. (B1 to 4- one plane, B5 to 8- one plane, B9- normal liver)

C. The specimen received in formalin consists of a gallbladder, measuring 8.5cm in length and 4cm in diameter. The serosa surface is grossly unremarkable. The mucosa surface shows pinkish velvety. There is several yellowish small nodule, measuring up to 0.2cm in diameter. Representative sections are embedded.

[page 3 of 3]
Frozen Section(1-2)

H&E(11), MT(1), RTC(1), D-PAS(1), Iron(1), Cytokeratin 7(1)

Source: NCI Genomic Data Commons file d25e856e-e827-40dd-84e2-fe875533e46f (TCGA-RC-A7SF.D4F398CC-0003-4C08-989F-3C60762B100F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).